Somatic mutation profile of tumor specimen TCGA-56-7582-01A (aliquot TCGA-56-7582-01A-11D-2042-08) from TCGA case TCGA-56-7582, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.0 years (30,678 days).
Specimen TCGA-56-7582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01d5d338-75d5-4cf5-868e-5d8cdc000272.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7582-10A (Blood Derived Normal), aliquot TCGA-56-7582-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de28fcca-a567-43b8-a495-81665965bdac

The open-access MAF lists 176 somatic variants for this specimen: 136 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 38, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 4, Intron 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960212, COSV67961561; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 36/49 reads (73%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2ML1 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV100228988; called by muse, mutect2, varscan2
- ABCA8 | c.3185A>G p.H1062R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1302597044, COSV99285963; called by muse, mutect2, varscan2
- ABCB4 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.483); catalogued as COSV55935938; called by muse, mutect2, varscan2
- ABCB5 | c.3657C>G p.N1219K (on ENST00000404938 / NM_001163941.2; = p.N774K on NM_178559.6) | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV51708334, COSV99327326, COSV99328542; called by muse, mutect2, varscan2
- ABCC10 | c.1747C>A p.Q583K (on ENST00000372530 / NM_001198934.2; = p.Q540K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55094029, COSV99767350; called by muse, mutect2
- ADA2 | c.1063T>A p.F355I (on ENST00000262607; = p.F114I on NM_177405.3) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99376109; called by muse, mutect2, varscan2
- ADAMTS10 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1206816425, COSV54357811; called by muse, mutect2, varscan2
- ADGRB3 | c.3230C>A p.A1077D | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99485409, COSV99486799; called by muse, mutect2, varscan2
- AGAP2 | c.1588G>A p.A530T (on ENST00000547588 / NM_001122772.2; = p.A194T on NM_014770.4) | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs759169163, COSV99223367; called by muse, mutect2, varscan2
- AK9 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs148574935; called by muse, varscan2
- AMOT | c.1921C>T p.Q641* (on ENST00000371959 / NM_001113490.1; = p.Q232* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 50/66 reads (76%) | catalogued as COSV100495121; called by muse, mutect2, varscan2
- ANO4 | c.2647G>T p.A883S (on ENST00000392977 / NM_001286615.2; = p.A848S on NM_178826.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100153019; called by muse, mutect2, varscan2
- APOB | c.6996G>T p.E2332D | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99265925; called by muse, mutect2, varscan2
- ARFGAP3 | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.437); catalogued as COSV99605321; called by muse, mutect2, varscan2
- B3GLCT | c.1232G>A p.C411Y | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs751428014, COSV100587334; called by muse, mutect2, varscan2
- BAZ1A | c.930A>T p.K310N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100701160; called by muse, mutect2, varscan2
- BCLAF1 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100786708; called by mutect2, varscan2
- BFSP2 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV100183783; called by muse, mutect2, varscan2
- BRD4 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99650803; called by muse, mutect2, varscan2
- C12orf65 | c.91T>G p.L31V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99473970; called by muse, mutect2, varscan2
- CACNA1G | c.5498C>A p.S1833Y | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100661908, COSV61732449; called by muse, mutect2, varscan2
- CAMK4 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.244); catalogued as COSV99999485; called by muse, mutect2, varscan2
- CCDC14 | c.1846G>A p.D616N (on ENST00000488653; = p.D568N on NM_022757.5) | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100113249, COSV100113449; called by muse, mutect2, varscan2
- CCDC9 | c.1531C>G p.P511A | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV99699729; called by muse, mutect2, varscan2
- CD82 | c.327C>A p.N109K | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV99907618; called by muse, mutect2, varscan2
- CDC40 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as COSV100309387; called by muse, mutect2, varscan2
- CDKN2A | c.166del p.S56Afs*90 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as COSV58711270; called by mutect2, varscan2
- CENPF | c.1454A>G p.K485R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV100871709; called by muse, mutect2, varscan2
- CEP120 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV100071165; called by muse, mutect2, varscan2
- CEP170 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.119); catalogued as COSV100317182; called by muse, mutect2, varscan2
- CEP68 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99560972; called by muse, mutect2, varscan2
- CKAP5 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs751076163, COSV100370861; called by muse, mutect2, varscan2
- CLEC14A | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100643604; called by muse, mutect2, varscan2
- COBL | c.551T>G p.I184S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99472791; called by muse, mutect2, varscan2
- COL11A1 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100616845; called by muse, mutect2, varscan2
- COPG1 | c.871+1G>A p.X291_splice | Splice Site (SNP) | VAF 52/167 reads (31%) | catalogued as COSV100135657; called by muse, mutect2, varscan2
- CORO2B | c.665A>T p.N222I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99963327; called by muse, mutect2, varscan2
- CPT1C | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV99773490; called by muse, mutect2, varscan2
- CUEDC1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs758136599, COSV100804764; called by muse, varscan2
- DHX8 | c.2912G>A p.G971D | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301024547, COSV99292290; called by muse, mutect2, varscan2
- DKKL1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.019); catalogued as COSV55563227; called by muse, mutect2, varscan2
- DLEC1 | c.2244A>T p.K748N | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57302624; called by muse, mutect2, varscan2
- DNAH7 | c.4757C>T p.A1586V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100415483; called by muse, mutect2, varscan2
- DNAH9 | c.11158G>A p.D3720N | Missense Mutation (SNP) | VAF 127/159 reads (80%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1567880061, COSV99306143; called by muse, mutect2, varscan2
- ELAC2 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100568529, COSV62033327; called by muse, mutect2, varscan2
- ELAPOR1 | c.2725C>A p.L909M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100884440; called by muse, mutect2, varscan2
- EPB41L3 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59471224; called by muse, mutect2, varscan2
- EPG5 | c.1597A>T p.M533L | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99957414; called by muse, mutect2, varscan2
- ETS1 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs910334116, COSV101200336; called by muse, mutect2, varscan2
- F5 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs375248946; called by muse, mutect2, varscan2
- FAM120A | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs375343661; called by muse, mutect2, varscan2
- FAM151B | c.536-1G>A p.X179_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99971711, COSV99971735; called by muse, mutect2, varscan2
- FGR | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV100925840; called by muse, mutect2, varscan2
- FOXL2NB | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100374592; called by muse, mutect2, varscan2
- FSCB | c.2437G>A p.V813I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100469401; called by muse, mutect2, varscan2
- GGT5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1161844017, COSV99571590; called by muse, mutect2, varscan2
- GRM8 | c.1548C>A p.C516* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV100281921, COSV100283381; called by muse, mutect2, varscan2
- GRM8 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100283384; called by muse, mutect2, varscan2
- HK2 | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV99309129; called by muse, mutect2, varscan2
- HPS4 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773931864, COSV100404382; called by muse, mutect2, varscan2
- IGF2BP1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs1291250091, COSV99288688; called by muse, mutect2
- IGKV2-30 | c.176A>T p.N59I | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as rs781503495; called by muse, mutect2, varscan2
- INO80 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62739744, COSV62742047; called by muse, mutect2, varscan2
- IRF2BP2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1194029127, COSV100784329; called by muse, mutect2, varscan2
- IRGC | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as rs184064504, COSV54985270, COSV99746344; called by muse, mutect2, varscan2
- ISCA1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100276484, COSV100276531; called by muse, mutect2, varscan2
- KCTD11 | c.591G>T p.E197D (on ENST00000333751 / NM_001363642.1; = p.E158D on NM_001002914.2) | Missense Mutation (SNP) | VAF 79/101 reads (78%) | SIFT tolerated (0.43); PolyPhen benign (0.283); catalogued as COSV99341715; called by muse, mutect2, varscan2
- KIT | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99854410; called by muse, mutect2, varscan2
- LCT | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759909031, COSV51548074, COSV99929322; called by muse, mutect2, varscan2
- LGR5 | c.356+1G>T p.X119_splice | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99878002; called by muse, mutect2, varscan2
- LMF2 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 144/226 reads (64%) | catalogued as rs771887975, COSV99327600; called by muse, mutect2, varscan2
- LRRC52 | c.215A>G p.H72R | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99673912; called by muse, mutect2, varscan2
- MAML2 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV101594129, COSV73264522; called by muse, mutect2, varscan2
- MFSD14A | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV100924611; called by muse, mutect2, varscan2
- MMP2 | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99527881; called by muse, mutect2, varscan2
- MYO10 | c.5572C>G p.Q1858E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV99945533; called by muse, mutect2, varscan2
- MYO18B | c.6679C>T p.P2227S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100123845; called by muse, mutect2, varscan2
- NF1 | c.6007-1G>T p.X2003_splice (on ENST00000358273 / NM_001042492.3; = p.X1982_splice on NM_000267.3) | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as CS040854, CS1512939, COSV62212605, COSV62214837; called by muse, mutect2, varscan2
- NFKB2 | c.1835G>T p.S612I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99192773; called by muse, mutect2, varscan2
- NFYA | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1268778598, COSV100399696; called by muse, mutect2, varscan2
- NIF3L1 | c.257C>A p.A86E (on ENST00000409020 / NM_001369444.1; = p.A59E on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99626832; called by muse, mutect2, varscan2
- NRK | c.1895C>A p.A632E | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV99688034; called by muse, mutect2, varscan2
- NYAP2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56014060; called by muse, mutect2, varscan2
- OOEP | c.9T>A p.D3E | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV100949831; called by muse, mutect2, varscan2
- OR2T27 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100788271, COSV100788301; called by muse, mutect2, varscan2
- OR4C16 | c.761T>C p.F254S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100114086; called by muse, mutect2, varscan2
- OR6A2 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV100215753; called by muse, mutect2, varscan2
- OR8J1 | c.834T>A p.F278L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100275035; called by muse, mutect2, varscan2
- PARP9 | c.1969C>A p.Q657K | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100831180, COSV64451680; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.035); catalogued as rs746750418, COSV59016548; called by muse, mutect2, varscan2
- PIK3CD | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV100740229; called by muse, mutect2, varscan2
- PLA2G4C | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1015873702, COSV100843956; called by muse, mutect2, varscan2
- PLEC | c.8922G>C p.E2974D (on ENST00000322810 / NM_201380.4; = p.E2864D on NM_000445.5) | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs369984112, COSV100514870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLDIP3 | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs747338994, COSV99349113; called by muse, mutect2, varscan2
- POTEF | c.2807T>A p.L936Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV100664933, COSV100664978; called by muse, varscan2
- PPP1R9A | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV99195820; called by muse, mutect2
- QRICH2 | c.2347C>A p.H783N | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.318); catalogued as COSV99429310; called by muse, mutect2, varscan2
- RBBP6 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.63); catalogued as COSV100154636; called by muse, mutect2, varscan2
- RHOBTB2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1262647537, COSV52572435; called by muse, mutect2, varscan2
- RYK | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99938461; called by muse, mutect2, varscan2
- SCN8A | c.4291C>A p.Q1431K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100633895; called by muse, mutect2
- SDK1 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as COSV101269435; called by muse, mutect2, varscan2
- SEL1L | c.2237A>C p.Y746S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100377935; called by muse, mutect2, varscan2
- SIGLEC11 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV101389405; called by muse, mutect2, varscan2
- SIN3B | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56131878, COSV99931774; called by muse, mutect2, varscan2
- SLC24A2 | c.789G>T p.W263C | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99646764; called by muse, mutect2, varscan2
- SLC30A8 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.407); catalogued as COSV101438536, COSV69969577; called by muse, mutect2, varscan2
- SLC49A3 | c.1619C>A p.A540E (on ENST00000404286 / NM_001294341.2; = p.A539E on NM_032219.4) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV100448463; called by muse, mutect2, varscan2
- SLITRK2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 27/37 reads (73%) | catalogued as COSV100157824; called by muse, mutect2, varscan2
- SPHKAP | c.1993A>T p.N665Y | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100764156; called by muse, mutect2, varscan2
- STARD5 | c.609C>G p.N203K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100250853; called by muse, mutect2, varscan2
- TAAR6 | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV99256748; called by muse, mutect2, varscan2
- TAS2R41 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 72/89 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0.098); catalogued as COSV101281493; called by muse, varscan2
- THSD7A | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749447777, COSV101448741, COSV70263548; called by muse, mutect2, varscan2
- THSD7A | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 41/66 reads (62%) | catalogued as rs745415841, COSV70263921; called by muse, mutect2, varscan2
- TTN | c.89881C>A p.P29961T (on ENST00000591111; = p.P22537T on NM_003319.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen benign (0.202); catalogued as COSV100615966; called by muse, mutect2, varscan2
- TTPA | c.754A>T p.M252L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99478540; called by muse, mutect2, varscan2
- UCK2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.274); catalogued as COSV100902998; called by muse, mutect2, varscan2
- VPS13D | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV100693144; called by muse, mutect2, varscan2
- WDHD1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs993714999, COSV62212980; called by muse, mutect2
- WDR33 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100460176; called by muse, mutect2, varscan2
- ZBED6CL | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV100550534; called by muse, mutect2, varscan2
- ZFP30 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV100665939; called by muse, mutect2, varscan2
- ZNF143 | c.1908G>T p.L636F | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV100217874; called by muse, varscan2
- ZNF609 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1381024670, COSV100441151; called by muse, mutect2
- ZNF665 | c.671C>T p.P224L (on ENST00000600412; = p.P289L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99081243; called by muse, mutect2, varscan2
- ZNF707 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100690630; called by muse, mutect2, varscan2
- ZP3 | c.1183G>T p.A395S (on ENST00000394857 / NM_001110354.2; = p.A344S on NM_007155.6) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as COSV100334553; called by muse, mutect2, varscan2
- ZSCAN5B | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs1315208494, COSV61999434, COSV62001651; called by muse, mutect2, varscan2
- AHNAK | c.7476del p.V2494Lfs*3 | Frame Shift Del (DEL) | VAF 138/239 reads (58%) | called by mutect2, pindel, varscan2
- LRRTM1 | c.340del p.R114Efs*7 | Frame Shift Del (DEL) | VAF 49/182 reads (27%) | called by mutect2, pindel, varscan2
- NIPBL | c.1670_1672del p.I557del | In Frame Del (DEL) | VAF 76/285 reads (27%) | called by mutect2, pindel, varscan2
- TRAV3 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- WDR35 | c.66del p.W22* | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, varscan2
- APOL5 | c.1044G>T p.R348= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV99968399; called by muse, mutect2, varscan2
- ARSG | c.1311C>T p.A437= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV100048450; called by muse, mutect2, varscan2
- CIT | c.2214C>T p.D738= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV99949852; called by muse, mutect2, varscan2
- CLCN2 | c.1290C>T p.N430= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as rs185438143, COSV55603257; called by muse, mutect2, varscan2
- COL28A1 | c.414C>A p.S138= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101258652; called by muse, mutect2, varscan2
- CPED1 | c.2952C>T p.S984= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100120858; called by muse, mutect2, varscan2
- EARS2 | c.1158C>T p.C386= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV101492170; called by muse, mutect2, varscan2
- EPB41L3 | c.3129G>T p.G1043= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100549353; called by muse, mutect2, varscan2
- FAP | c.1896G>T p.L632= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99502034; called by muse, mutect2, varscan2
- FLG | c.8829T>A p.S2943= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as COSV100911630; called by mutect2, varscan2
- FOXS1 | c.606C>T p.C202= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1021794350, COSV54068014; called by muse, mutect2, varscan2
- HEPHL1 | c.1653C>T p.S551= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as COSV100243998, COSV59891961; called by muse, mutect2, varscan2
- HIPK2 | c.2853C>T p.D951= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV100702279; called by muse, mutect2, varscan2
- IGF1R | c.2814C>T p.I938= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs199780163, COSV99151556; called by muse, mutect2, varscan2
- IL20 | c.505C>T p.L169= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100894156; called by muse, mutect2, varscan2
- LRP1B | c.7059T>C p.N2353= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV101257720; called by muse, mutect2, varscan2
- LRRK2 | c.1827T>C p.L609= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100110350; called by muse, mutect2, varscan2
- MRPS30 | c.696G>A p.Q232= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs1299647293, COSV50181718; called by muse, mutect2, varscan2
- NAV3 | c.582G>A p.Q194= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99891682; called by muse, mutect2, varscan2
- PAEP | c.153G>A p.A51= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs750815074, COSV99478941; called by muse, mutect2, varscan2
- PHKA2 | c.1134C>T p.N378= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101177117; called by muse, varscan2
- PRB2 | c.768C>T p.P256= | Silent (SNP) | VAF 72/568 reads (13%) | catalogued as rs1204002250; called by muse, varscan2
- PRKACG | c.1014C>A p.I338= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99599013; called by muse, mutect2, varscan2
- RIMS1 | c.1893T>C p.L631= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99327397; called by muse, mutect2, varscan2
- RIMS4 | c.555G>A p.L185= | Silent (SNP) | VAF 134/388 reads (35%) | catalogued as COSV100865133; called by muse, varscan2
- SALL1 | c.1050C>A p.T350= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV99174306; called by muse, mutect2, varscan2
- SEL1L | c.912C>G p.G304= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100377939; called by muse, mutect2, varscan2
- SHOX2 | c.792G>A p.L264= (on ENST00000441443 / NM_006884.3; = p.L288= on NM_003030.4) | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV101273799; called by muse, mutect2, varscan2
- SKP2 | c.186G>A p.P62= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV99682894; called by muse, mutect2, varscan2
- SLC6A5 | c.2166C>A p.L722= | Silent (SNP) | VAF 117/138 reads (85%) | catalogued as COSV100116930; called by muse, mutect2, varscan2
- SOX17 | c.285C>T p.N95= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs976208695, COSV52028577; called by muse, mutect2, varscan2
- SPICE1 | c.580C>T p.L194= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99871427; called by muse, mutect2, varscan2
- SYT16 | c.990A>G p.P330= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as rs760120499, COSV101413633; called by muse, mutect2, varscan2
- TXNDC11 | c.343C>T p.L115= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99297842; called by muse, mutect2, varscan2
- VIRMA | c.4479C>G p.L1493= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV52591436, COSV99888525; called by muse, mutect2, varscan2
- ZDHHC19 | c.15G>A p.T5= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs755156004, COSV56349861; called by muse, mutect2, varscan2
- ZFHX3 | c.7254C>G p.T2418= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs746447934, COSV99213024; called by muse, mutect2, varscan2
- ZFPM2 | c.3186C>T p.N1062= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as CD152244, COSV101023243; called by muse, mutect2
- IGKV1-13 | n.34C>A | RNA (SNP) | VAF 24/202 reads (12%) | called by muse, varscan2
- MACF1 | c.15832-10299C>T | Intron (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99244769; called by muse, mutect2, varscan2
